Gene-level copy-number profile of specimen HCM-WCMC-1292-C67-85A from HCMI case HCM-WCMC-1292-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; Tumor grade: G3; Age at diagnosis: 60.3 years (22,029 days).
Specimen HCM-WCMC-1292-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bb72e838-890b-45af-9086-a1b006ea74b0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-1292-C67-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/7a79781b-3505-48e3-8ec7-69f92e724b44

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 814; copy number 2: 14,796; copy number 3: 23,589; copy number 4: 13,897; copy number 5: 3,489; copy number 6: 1,231; copy number 7: 35; copy number 8: 159; copy number 9: 548; copy number 10: 99; copy number 11: 145; copy number 12: 28; copy number 13: 15; copy number 14: 16; copy number 19: 21; copy number 36: 5; copy number 51: 7.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–140,899,106, 1 gene (within-gene range 0–2): LRRC57P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,078 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,938,744–147,699,335, 27 genes, copy number 7: NBPF12, PFN1P8, AC244394.3, AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1.
- chr1:147,840,962–147,909,269, 2 genes, copy number 7: AC239801.1, GJA8.
- chr1:150,211,632–153,958,615, 214 genes, copy number 8–14 (broad region; genes not listed).
- chr5:58,198–21,589,372, 356 genes, copy number 8–14 (broad region; genes not listed).
- chr5:21,750,673–45,895,970, 322 genes, copy number 8–9 (within-gene range 6–9) (broad region; genes not listed).
- chr11:13,054,615–13,152,348, 2 genes, copy number 7: AC013762.1, AC022878.1.
- chr12:55,113,077–55,124,120, 2 genes, copy number 7: OR9K1P, AC027287.1.
- chr15:20,916,686–20,935,658, 1 gene, copy number 7: NF1P1.
- chr15:21,053,004–21,054,702, 1 gene, copy number 10: AC037471.1.
- chr19:44,326,555–44,401,608, 3 genes, copy number 8 (within-gene range 6–8): ZNF112, AC245748.1, ZNF285.
- chr20:30,214,765–30,214,976, 1 gene, copy number 7: CFTRP3.
- chr20:30,484,925–35,092,807, 147 genes, copy number 11–51 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 343. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
